CCDI case PBBNVX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3706c2be-8d2b-43c7-b9e1-6fd35b11af20

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.4 years (890 days).

Biospecimens (4 samples)
- Sample 0DE5NB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE5OO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DE5R6, 0DEFJU (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
